Somatic mutation profile of tumor specimen C3L-05320-54 (aliquot CPT0339870002) from CPTAC case C3L-05320, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 29.0 years (10,606 days).
Specimen C3L-05320-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c02ac339-d66c-4815-b02e-a1b60c9afa89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05320-50 (Buccal Cell Normal), aliquot CPT0339840004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6932d812-0ffc-461f-8045-2d7f8f0f98e3

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DAXX | c.380T>G p.I127S | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLSTN1 | c.1122G>A p.P374= (on ENST00000377298 / NM_001009566.3; = p.P364= on NM_014944.4) | Silent (SNP) | VAF 16/234 reads (7%) | catalogued as rs751925496; called by muse, mutect2
- PCDHA13 | c.1914C>T p.D638= | Silent (SNP) | VAF 16/315 reads (5%) | catalogued as COSV56497698; called by muse, mutect2
- WWC1 | c.822G>A p.P274= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as rs1356011702; called by muse, mutect2
